Surgical pathology report (de-identified scan), TCGA case TCGA-97-8552, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-8552-01A (Primary Tumor).

[page 1 of 9]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. BASILAR SEGMENT LEFT LOWER LOBE
2. LEVEL 11 LYMPH NODE, LEFT
3. LEVEL 5 LYMPH NODE, LEFT
4. LEVEL 6 LYMPH NODE, LEFT
5. LEVEL 7 LYMPH NODE
- SEE ADDENDUM

Reason For Addendum #1: Molecular Studies

Reason For Addendum #2: Molecular Studies

Reason For Addendum #3: Molecular Studies

DIAGNOSIS:

**1. LUNG, LEFT LOWER LOBE, BASILAR SEGMENT: SEGMENTECTOMY
- ADENOCARCINOMA, LEPIDIC PREDOMINANT (1.5 CM), SEE NOTE.
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.**

Note: The tumor consists of lepidic (70%), papillary (20%), micropapillary (5%) and acinar (5%) components. There is an area of invasion measuring 0.7 cm in greatest linear dimension. Results of mutational studies will be reported in addenda.

**2. LYMPH NODE, LEFT LEVEL 11: BIOPSY
- ONE BENIGN LYMPH NODE (0/1).**

**3. LYMPH NODE, LEFT LEVEL 5: BIOPSY
- ONE BENIGN LYMPH NODE (0/1).**

**4. LYMPH NODE, LEFT LEVEL 6: BIOPSY
- ONE BENIGN LYMPH NODE (0/1).**

**5. LYMPH NODE, LEVEL 7: BIOPSY
- ONE BENIGN LYMPH NODE (0/1).**

**Specimens: 1: BASILAR SEGMENT LEFT LOWER LOBE
2: LEVEL 11 LYMPH NODE, LEFT
3: LEVEL 5 LYMPH NODE, LEFT
4: LEVEL 6 LYMPH NODE, LEFT**

[page 2 of 9]
5: LEVEL 7 LYMPH NODE

LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)

left lower lobe

Procedure: Segmentectomy

Specimen Laterality: Left

Tumor Site: Lower lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma, mixed subtype

Histologic Grade: G1: Well differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

1.5cm

Visceral Pleura Invasion: Not identified

MARGINS

Bronchial Margin

Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by invasive carcinoma

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

STAGE (pTNM)

Primary Tumor (pT):

pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (i.e., not in the main bronchus); or Superficial spreading tumor of any size with its invasive component limited to the bronchial wall, which may extend proximally to the main bronchus

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number Examined

4

Number Involved

0

Distant Metastases (pM): Not applicable

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

never-smoker with a 1.5 cm LLL nodule.

[page 3 of 9]
MACROSCOPIC DESCRIPTION:

The specimen is received in saline, in five parts, each labeled with the patient's name.

1. Part one is labeled 'basilar segment left lower lobe, stitch marks tumor'. It consists of a segmentectomy specimen of the lung measuring 15 x 10 x 4 cm. The staple line measures 8 cm in length which is shaved and the parenchyma around is inked black. The specimen is received precut and the precut area is marked with a stitch which reveals a gray-pink slightly firm nodule measuring 1.5 x 1.2 cm. The nodule is located subpleural and 3 cm from the hilum. The pleura is gray-pink, glistening and lightly mottled with fine black streaks. The remainder of the parenchyma is pink-red, blotchy and crepitant. Representative sections are submitted.

2. Part two is labeled 'level 11 lymph node left'. It consists of one anthracotic lymph node measuring 0.8 x 0.6 x 0.3 cm. Entire lymph node is submitted in one cassette.

3. Part three is labeled 'level 5 lymph node left'. It consists of one anthracotic lymph node measuring 1 x 0.8 x 0.5 cm. Entire lymph node is submitted in one cassette.

4. Part four is labeled 'level 6 lymph node left'. It consists of one lymph node measuring 0.6 x 0.5 x 0.3 cm. Entire lymph node is submitted in one cassette.

5. Part five is labeled 'level 7 lymph node'. It consists of one anthracotic lymph node measuring 0.3 x 0.3 x 0.2 cm. Entire lymph node is submitted in one cassette.

SUMMARY OF SECTIONS:

1A-1C nodule from the stitch area
1D staple line margin
1E bronchial resection margin, shaved
1F random section of the lung parenchyma
2A in toto
3A in toto
4A in toto
5A in toto

SPECIAL PROCEDURES:

[page 4 of 9]
Final Diagnosis performed by

[REDACTED]

ADDENDUM #1 FOR MOLECULAR TESTS:

KRAS, EGFR and ALK FISH were sent 0 [REDACTED] 2 for

. The test is to be performed on tissue from case [REDACTED]

[REDACTED]
[REDACTED] accession number were retrieved from archives. The pathologist whose signature appears below reviewed the original pathology report, examined candidate H&E slides, and selected block 1A appropriate to the specifications of the ordered molecular analysis. x1 H&E and x9 unstained slides were prepared and forwarded to [REDACTED] where the subject molecular test will be performed. An addendum report will be issued when the results of this molecular test are available.

Addendum #1 performed by

[REDACTED]

ADDENDUM #2:

MOLECULAR ONCOLOGY

KRAS MUTATION ANALYSIS

[REDACTED]

RESULTS: Wild-type gene

[page 5 of 9]
INTERPRETATION: No mutations were identified at codons 12 and 13 of the KRAS gene.

COMMENT:

Mutations in the KRAS gene are reported to be associated with poor prognosis, and resistance to targeted tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer (NSCLC).

KRAS mutations occur in 15-30% of NSCLC patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected. This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

Analysis of EGFR mutation or gene amplification status may provide additional information regarding this patient's probability of response to targeted tyrosine kinase inhibitor therapies, if clinically indicated. See references.

METHOD/LIMITATIONS:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

[REDACTED]

[page 6 of 9]
[REDACTED]

[REDACTED]

[REDACTED] G

[REDACTED]

Addendum #2 performed by

[REDACTED]

ADDENDUM #3:

INTEGRATED ONCOLOGY

EGFR Mutation Analysis

[REDACTED]

[REDACTED]

[page 7 of 9]
Body Site: Left lower lobe of lung

Clinical Data: Adenocarcinoma

RESULTS: Positive for the E746_A750del5 mutation in Exon 19.

INTERPRETATION: Deletion mutations in exon 19, mostly involving the LREA motif, are reported to correlate with responsiveness to EGFR tyrosine kinase inhibitor in patients with non-small-cell lung carcinoma.

COMMENT: Forty percent (40%) or more tumor cellularity is optimal for this mutation analysis. The sample submitted showed 80% tumor cellularity upon pathologist review.

E746_A750del5 corresponds to 2236_2250del15.

A frequently occurring sequence change 2361G>A (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the samples, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by

[page 8 of 9]
bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 9 of 9]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 20e394fa-8304-439f-84cf-bb858ca85b24 (TCGA-97-8552.0BFE6DEE-7584-4803-BE3E-5201CD5AD412.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).